Somatic mutation profile of tumor specimen TARGET-10-PARNGI-09A (aliquot TARGET-10-PARNGI-09A-01D) from TARGET case TARGET-10-PARNGI, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.7 years (988 days).
Specimen TARGET-10-PARNGI-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b8ee2f91-f2e2-46cb-9f5e-8d5f3de7fe9d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARNGI-10A (Blood Derived Normal), aliquot TARGET-10-PARNGI-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3388e000-268f-43fd-9620-da9f92f7c129

The open-access MAF lists 12 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 3, Frame Shift Ins 2, 3'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- JAK2 | c.2049A>T p.R683S | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519723, COSV67569539, COSV67577012; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ITGA2 | c.2782C>G p.L928V | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.012); catalogued as COSV56866360; called by muse, mutect2, varscan2
- SCN10A | c.1642C>T p.P548S | Missense Mutation (SNP) | VAF 48/103 reads (47%) | SIFT tolerated (0.56); PolyPhen benign (0.041); catalogued as COSV71862628; called by muse, mutect2, varscan2
- SLC22A6 | c.482G>A p.R161H | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs1436310708; called by muse, mutect2, varscan2
- SPEG | c.4349G>A p.R1450Q | Missense Mutation (SNP) | VAF 88/210 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.141); catalogued as COSV56668111; called by muse, mutect2, varscan2
- C12orf40 | c.1211_1212insC p.R404Sfs*6 | Frame Shift Ins (INS) | VAF 14/36 reads (39%) | called by mutect2, pindel, varscan2
- IGHV2-70D | c.355_358delinsGCACGTGGA p.I119Afs*? | Frame Shift Ins (INS) | VAF 27/43 reads (63%) | called by pindel, varscan2*
- ARHGAP6 | c.1548C>T p.C516= | Silent (SNP) | VAF 31/32 reads (97%) | catalogued as rs765786974, COSV57291516; called by muse, mutect2, varscan2
- MAP1A | c.792T>C p.R264= | Silent (SNP) | VAF 66/142 reads (46%) | called by muse, mutect2, varscan2
- TMEM132C | c.2460C>T p.H820= | Silent (SNP) | VAF 68/164 reads (41%) | catalogued as rs561705907, COSV59414400; called by muse, mutect2
- AC005865.1 | chr12:3298219 A>G | 3'Flank (SNP) | VAF 52/112 reads (46%) | catalogued as rs755256754; called by muse, mutect2, varscan2
- OR1F2P | n.196A>C | RNA (SNP) | VAF 71/176 reads (40%) | catalogued as rs754158407; called by muse, mutect2, varscan2
